Gene-level copy-number profile of tumor specimen TCGA-FG-5963-02A from TCGA case TCGA-FG-5963, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 23.5 years (8,571 days).
Specimen TCGA-FG-5963-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.c6242282-65a4-4b6d-8521-b2a44a399afe.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FG-5963-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 362 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6b298aac-bae0-43ea-9d19-b2663ceda337

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 192; copy number 1: 21,447; copy number 2: 34,652; copy number 3: 3,693; copy number 4: 272; copy number 5: 3; copy number 8: 1; copy number 9: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FG-5963-02A-12D-A29P-01): tumor purity 0.74, ploidy 3.42, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 192 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:155,525,424–155,664,668, 1 gene (within-gene range 0–3): AC073225.1.
- chr2:156,033,247–156,034,080, 1 gene: HEBP2P1.
- chr2:161,931,199–162,838,767, 14 genes: RPEP5, DPP4, DPP4-DT, TIMM8AP1, EIF3EP2, AC008063.1, GCG, AC007750.1, FAP, IFIH1, GCA, KCNH7, RNA5SP109, KCNH7-AS1.
- chr3:72,996,803–75,339,071, 24 genes (within-gene range 0–1): PPP4R2, RNU7-19P, EBLN2, RNU6-557P, RNU2-64P, CCDC75P1, RNU6-1270P, PDZRN3, RNU7-119P, PDZRN3-AS1, AC117489.1, AC108725.1, LINC02005, Metazoa_SRP, LINC02047, AC016930.1, AKR1B1P2, CNTN3, NIPA2P2, RN7SL294P, MIR4444-2, AC117481.1, HNRNPA3P6, MYLKP1.
- chr3:75,906,695–77,811,844, 7 genes: ROBO2, Y_RNA, CAP1P1, RNU6-386P, VDAC1P7, AC133040.1, RNU6-217P.
- chr3:78,525,101–79,767,998, 4 genes (within-gene range 0–1): MRPS17P3, ROBO1, AC055731.1, RN7SL751P.
- chr9:20,331,446–26,895,970, 97 genes (broad region; genes not listed).
- chr11:11,239,759–12,668,495, 24 genes: MTND5P21, KC877392.1, GALNT18, CSNK2A3, AC023946.1, AC104031.1, MIR4299, AC131935.2, AC131935.1, AC104383.1, MIR8070, USP47, H3P33, DKK3, LINC02547, AC124276.1, AC124276.2, MICAL2, MIR6124, AC079329.1, AC025300.1, PARVA, AC009806.1, AC107881.1.
- chr12:38,274,448–38,274,549, 1 gene: Y_RNA.
- chr14:106,425,359–106,443,583, 4 genes: IGHV7-40, AC244452.1, IGHVII-40-1, IGHV3-41.
- chr14:106,770,577–106,875,071, 15 genes: IGHV2-70, IGHV3-71, IGHV3-72, IGHV3-73, IGHV3-74, IGHVII-74-1, IGHV3-75, IGHV3-76, IGHVIII-76-1, MIR5195, IGHV5-78, IGHVII-78-1, IGHV3-79, IGHV4-80, IGHV7-81.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:219,289,623–219,333,177, 3 genes, copy number 5 (within-gene range 2–5): PTPRN, AC114803.1, RESP18.
- chr10:95,109,136–95,111,642, 1 gene, copy number 9: AL157834.1.
- chr21:45,914,296–45,919,483, 1 gene, copy number 8: AJ239328.1.

Autosomal genes at a single copy (total copy number 1): 19,058. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
